PECGS case C083-000017 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/8bf8a6a0-d92d-4379-a0b7-172eb48bfb9f

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 72 years; Year of birth: 1942; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma in tubulovillous adenoma: ICD-O-3 morphology code: 8263/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 72.4 years (26,444 days); AJCC pathologic stage: Stage IIA; Progression or recurrence: yes; Days to last follow up: 1,282 days (3.5 years).

Other clinical attributes
- BMI: 23.62; Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Alcohol history: Yes.

Biospecimens (2 samples)
- Sample C083-000017_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000017_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
